Gene-level copy-number profile of tumor specimen TARGET-40-PAPXGT-01A from TARGET case TARGET-40-PAPXGT, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.4 years (4,172 days).
Specimen TARGET-40-PAPXGT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.e6deb34e-2573-54be-92f0-c2b593a0a081.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAPXGT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 395 have no estimate.
https://portal.gdc.cancer.gov/files/035e0d51-848f-4f19-8563-d00a298bcf0d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 568; copy number 1: 64; copy number 2: 17,106; copy number 3: 8,488; copy number 4: 29,137; copy number 5: 490; copy number 6: 4,065; copy number 7: 172; copy number 8: 113; copy number 9: 8; copy number 10: 13; copy number 11: 4.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 1 gene (within-gene range 0–2): AC109583.1.
- chr3:46,742,092–46,812,558, 2 genes (within-gene range 0–2): AC109583.4, AC109583.2.
- chr3:116,552,473–117,027,039, 10 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr6:73,971,346–75,206,053, 9 genes (within-gene range 0–2): AL590552.1, TXNP7, AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2, AL356473.1, COL12A1.
- chr6:169,419,004–169,781,600, 11 genes (within-gene range 0–2): AL009176.1, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3.
- chr17:7,686,071–7,885,238, 9 genes (within-gene range 0–2): WRAP53, EFNB3, DNAH2, RPL29P2, KDM6B, TMEM88, NAA38, CYB5D1, AC104581.4.
- chr19:20,340,269–20,424,969, 1 gene (within-gene range 0–3): ZNF826P.
- chr19:20,389,658–20,571,095, 5 genes (within-gene range 0–3): AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 25 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:14,124,233–14,304,445, 2 genes, copy number 10 (within-gene range 6–10): RNU6-1265P, AL357873.1.
- chr6:46,018,745–46,207,386, 5 genes, copy number 10: RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9.
- chr12:76,137,425–76,559,809, 6 genes, copy number 10 (within-gene range 5–10): AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8.
- chr15:24,101,827–24,823,365, 1 gene, copy number 11 (within-gene range 2–11): PWRN1.
- chr15:24,206,784–24,343,464, 3 genes, copy number 11: AC087463.1, AC087463.2, AC087463.3.
- chr20:54,859,688–56,005,519, 8 genes, copy number 9: RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4.

Autosomal genes at a single copy (total copy number 1): 64. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
